Somatic mutation profile of tumor specimen ASCProject_0289_T1_WES (aliquot ASCProject_0289_T1_WES_1) from CMI case ASCProject_0289, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 62.8 years (22,949 days).
Specimen ASCProject_0289_T1_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Chest Wall; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2689586-ea86-4e47-8358-2d47a18a34a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0289_SALIVA (Saliva), aliquot ASCProject_0289_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79290c58-38e6-45e8-addc-a25385237b08

The open-access MAF lists 37 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, 3'UTR 7, Silent 6, RNA 3, Intron 2, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH5A1 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72552281, CM033318; ClinVar: pathogenic; called by mutect2, varscan2
- CAPNS1 | c.138_158del p.G50_G56del | In Frame Del (DEL) | VAF 6/54 reads (11%) | catalogued as rs779030286; called by mutect2, varscan2
- FLT4 | c.3208C>T p.R1070C | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774554521, COSV56112322, COSV99987558; called by muse, mutect2, varscan2
- HMCN1 | c.11218C>G p.P3740A | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54949604; called by muse, mutect2, varscan2
- LONP1 | c.1489G>A p.V497I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as rs148214998; called by mutect2, varscan2
- MUC4 | c.10174C>G p.P3392A | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.55); catalogued as rs761575788, COSV57791841; called by muse, mutect2
- TPR | c.5683G>A p.G1895R | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.378); catalogued as COSV66604287; called by mutect2, varscan2
- UGT8 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.067); catalogued as rs374700060; called by mutect2, varscan2
- ZBTB48 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1417978097; called by muse, mutect2, varscan2
- CCDC27 | c.861+1del | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- ESCO2 | c.1567C>A p.Q523K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- GYG1 | c.322C>G p.L108V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- NTRK2 | c.1303G>T p.A435S | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- PLOD1 | c.136C>A p.R46S | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PSD | c.24C>A p.F8L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- RAD51AP2 | c.1039A>T p.S347C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RNF214 | c.1943C>G p.S648C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- SRGAP1 | c.1754G>C p.R585P | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYTL1 | c.1468G>C p.A490P (on ENST00000543823; = p.A478P on NM_032872.3) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- GRM5 | c.369A>G p.E123= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV100552424; called by muse, varscan2
- MAK | c.1647C>G p.S549= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV100504783; called by muse, mutect2, varscan2
- MYH7B | c.1158C>T p.S386= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs772026348; called by mutect2, varscan2
- MYLK3 | c.2436A>G p.L812= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- PCDHA13 | c.2178G>A p.P726= | Silent (SNP) | VAF 28/51 reads (55%) | catalogued as rs1474628802, COSV56501101; called by muse, mutect2, varscan2
- PRPS1L1 | c.165C>T p.I55= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as rs749613723, COSV72649918; called by muse, mutect2, varscan2
- DNAJC19 | c.*690A>G | 3'UTR (SNP) | VAF 4/31 reads (13%) | catalogued as rs1370714837, COSV104423365; called by muse, varscan2
- DNASE2 | c.*30A>C | 3'UTR (SNP) | VAF 4/25 reads (16%) | catalogued as rs914552111, COSV52243796; called by muse, varscan2
- DPPA3P2 | n.639del | RNA (DEL) | VAF 4/45 reads (9%) | called by pindel, varscan2
- FRA10AC1 | c.*19C>A | 3'UTR (SNP) | VAF 6/41 reads (15%) | called by mutect2, varscan2
- HFE | c.*2177A>G | 3'UTR (SNP) | VAF 4/24 reads (17%) | catalogued as rs1460397415; called by muse, varscan2
- KRT8P11 | n.113C>A | RNA (SNP) | VAF 5/31 reads (16%) | called by mutect2, varscan2
- R3HDM2 | c.*446A>G | 3'UTR (SNP) | VAF 4/10 reads (40%) | catalogued as rs1453353142; called by mutect2, varscan2
- SMIM27 | c.*902C>G | 3'UTR (SNP) | VAF 4/37 reads (11%) | catalogued as COSV63083608; called by muse, varscan2
- SNORD114-31 | n.9C>T | RNA (SNP) | VAF 4/26 reads (15%) | catalogued as rs753645973; called by mutect2, varscan2
- XIAP | c.*5652C>T | 3'UTR (SNP) | VAF 6/20 reads (30%) | catalogued as rs200661683; called by mutect2, varscan2
- XPA | c.673+2527G>A | Intron (SNP) | VAF 16/72 reads (22%) | called by muse, mutect2, varscan2
- ZNF726 | c.226+3352T>C | Intron (SNP) | VAF 8/72 reads (11%) | catalogued as rs1168105083; called by muse, varscan2
